MMRF case MMRF_2199 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c0a321ef-fcc6-429c-8b2c-98077a9fb317

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.8 years (28,430 days); ISS stage: I; Days to last known disease status: 848 days (2.3 years); Days to last follow up: 848 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 237 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 13 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 1.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.132 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 40 mg/dL; Immunoglobulin G 3.16 g/L; Immunoglobulin A 16.7 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.53 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 0.07 mg/dL.
- Day 127 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.511 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.525 mg/dL; Immunoglobulin G 3.66 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 7.15 mmol/L.
- Day 223 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.405 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.583 mg/dL; Immunoglobulin G 3.17 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.62 mmol/L.
- Day 281 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.847 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.07 mmol/L.
- Day 372 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 3.78 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.03 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.
- Day 456 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.836 mg/dL; Immunoglobulin G 3.93 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.44 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 4.95 mmol/L.
- Day 553 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.759 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 4.46 mmol/L.
- Day 666: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.615 mg/dL; Immunoglobulin G 4.79 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.79 mmol/L.
- Day 848: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.769 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 3.58 mmol/L.

Other clinical attributes
- Day 0: Weight: 63 kg; Height: 154 cm.

Biospecimens (2 samples)
- Sample MMRF_2199_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2199_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
